Somatic mutation profile of tumor specimen TCGA-FS-A1Z0-06A (aliquot TCGA-FS-A1Z0-06A-11D-A197-08) from TCGA case TCGA-FS-A1Z0, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 47.2 years (17,255 days).
Specimen TCGA-FS-A1Z0-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 642d2a4e-a2e0-4c01-a4e4-c9c7d8df2e16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1Z0-10A (Blood Derived Normal), aliquot TCGA-FS-A1Z0-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dde9a0eb-3761-4531-87f9-80e4a5c5d022

The open-access MAF lists 314 somatic variants for this specimen: 211 protein-altering or splice-affecting, 92 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 193, Silent 92, Nonsense Mutation 8, RNA 5, Splice Site 4, Splice Region 3, 3'UTR 2, Intron 2, 5'Flank 2, Frame Shift Del 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 67/115 reads (58%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABI1 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.485); catalogued as COSV61019131, COSV61019514; called by muse, mutect2, varscan2
- ADAMTS2 | c.2470G>A p.G824R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs867353605, COSV52377133; called by muse, mutect2, varscan2
- ADAMTS20 | c.2079G>A p.M693I | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as COSV101239017, COSV67136660; called by muse, mutect2, varscan2
- ADAMTS6 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66863135; called by muse, mutect2, varscan2
- ADGRL2 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as COSV54680746; called by mutect2, varscan2
- AFP | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as COSV99889641; called by muse, mutect2, varscan2
- ALAD | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as COSV52960135; called by muse, mutect2, varscan2
- ALG5 | c.913T>A p.F305I | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV53506636; called by mutect2, varscan2
- ANKRD30A | c.2792C>A p.T931N (on ENST00000611781; = p.T875N on NM_052997.2) | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV64617100; called by muse, mutect2, varscan2
- ARHGAP19 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57395001; called by muse, varscan2
- ARHGEF10L | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754179196, COSV51437992; called by muse, mutect2, varscan2
- ARHGEF17 | c.5885C>T p.P1962L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.251); catalogued as COSV55235845; called by muse, mutect2, varscan2
- ARMCX5 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55767258; called by muse, varscan2
- ASB1 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs1468903748, COSV52827913; called by muse, mutect2, varscan2
- ASTN1 | c.2927A>C p.N976T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV62502506; called by muse, mutect2, varscan2
- ASXL3 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52474715; called by mutect2, varscan2
- ATAD2 | c.3359C>T p.P1120L | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV54884965; called by muse, mutect2, varscan2
- ATP13A4 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs777828353, COSV55068396, COSV99794497; called by muse, mutect2, varscan2
- ATXN2 | c.1609C>T p.P537S (on ENST00000550104; = p.P377S on NM_002973.4) | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV66485285; called by muse, mutect2, varscan2
- C10orf71 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.11); catalogued as COSV100110383; called by mutect2, varscan2
- C2CD3 | c.5288C>T p.S1763F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58097790; called by muse, mutect2, varscan2
- C4BPA | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 74/113 reads (65%) | SIFT tolerated (0.69); PolyPhen benign (0.026); catalogued as COSV65537199, COSV65537328; called by muse, mutect2, varscan2
- C4orf50 | c.3+1G>A p.X1_splice (on ENST00000324058; = p.X1233_splice on NM_001364689.1 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 10/19 reads (53%) | catalogued as COSV100136062; called by muse, mutect2, varscan2
- CBX6 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53321698; called by mutect2, varscan2
- CCDC28A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100236622, COSV60425584; called by muse, mutect2, varscan2
- CCT5 | c.329T>C p.V110A | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54725014; called by muse, varscan2
- CD2AP | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as rs200440845, COSV63762216; called by muse, mutect2, varscan2
- CDH6 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs756992324, COSV54065713; called by muse, mutect2, varscan2
- CERCAM | c.1661C>T p.P554L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1377486274, COSV65711624; called by muse, mutect2, varscan2
- CFAP61 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV55641261; called by muse, mutect2, varscan2
- CFHR5 | c.1330+2T>C p.X444_splice | Splice Site (SNP) | VAF 8/63 reads (13%) | catalogued as COSV56826088; called by muse, mutect2
- CGAS | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 103/159 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64808772; called by muse, mutect2, varscan2
- CIC | c.2225C>T p.P742L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as COSV50583758; called by mutect2, varscan2
- CKAP5 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 86/242 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV56372054; called by muse, mutect2, varscan2
- CLBA1 | c.763C>T p.L255F | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.731); catalogued as COSV66348332; called by muse, mutect2, varscan2
- CNTN5 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV54341364; called by muse, mutect2, varscan2
- COL21A1 | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV55174091; called by muse, mutect2, varscan2
- COL22A1 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 190/305 reads (62%) | SIFT tolerated (0.23); PolyPhen benign (0.133); catalogued as rs1253727568, COSV100276845, COSV57352240; called by muse, mutect2, varscan2
- COL27A1 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.175); catalogued as rs987305955, COSV61929567; called by muse, mutect2, varscan2
- COL4A1 | c.3284C>T p.S1095F | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.997); catalogued as rs866175713, COSV65423124; called by muse, mutect2, varscan2
- CR1 | c.5009C>T p.S1670L | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV65461521; called by muse, mutect2, varscan2
- CX3CL1 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV50056606; called by muse, varscan2
- DCLK3 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV69364230; called by muse, mutect2, varscan2
- DDR1 | c.1487C>T p.S496F | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV61323644; called by muse, mutect2, varscan2
- DEPTOR | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as rs375937347; called by muse, mutect2, varscan2
- DIO3 | c.166G>T p.A56S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63774315; called by muse, mutect2, varscan2
- DNAH11 | c.5335C>T p.Q1779* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV100179377, COSV60972086; called by muse, mutect2
- DNAH3 | c.6544G>A p.D2182N | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759262393, COSV54540919; called by muse, mutect2, varscan2
- DNAH9 | c.9367G>A p.A3123T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as rs376876320; called by muse, mutect2, varscan2
- DOCK1 | c.3131C>T p.S1044L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV54753003; called by muse, mutect2, varscan2
- DOCK2 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV56978056; called by muse, mutect2, varscan2
- DOCK9 | c.5318C>T p.S1773L (on ENST00000376460 / NM_001366676.2; = p.S1774L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs765522851, COSV59639135; called by muse, mutect2, varscan2
- DQX1 | c.496G>A p.V166M | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs574005605, COSV66353530; called by mutect2, varscan2
- DSCAM | c.1685C>T p.S562L | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV68032826; called by muse, mutect2, varscan2
- DSP | c.3653A>T p.K1218M | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV65794509; called by muse, mutect2, varscan2
- DST | c.2755C>T p.R919C (on ENST00000361203 / NM_001374722.1; = p.R593C on NM_001723.6) | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141002593; called by muse, varscan2
- EMC1 | c.2774C>T p.A925V | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.836); catalogued as COSV64346337; called by muse, mutect2, varscan2
- ENPEP | c.2237C>T p.S746F | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as rs866342562, COSV54453168; called by muse, mutect2, varscan2
- ENPEP | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs1437266122, COSV54446763; called by muse, varscan2
- EPHB2 | c.1843G>A p.E615K (on ENST00000400191 / NM_001309193.2; = p.E616K on NM_004442.7) | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV65863907; called by muse, mutect2, varscan2
- ERC2 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs1470472841, COSV55649429; called by muse, mutect2, varscan2
- ERICH3 | c.2317G>A p.E773K | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs865943394, COSV58604950; called by muse, mutect2, varscan2
- ERN1 | c.2869T>A p.F957I | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV70503930; called by mutect2, varscan2
- EXOSC1 | c.469C>T p.H157Y | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.092); catalogued as COSV58356047; called by muse, mutect2, varscan2
- FA2H | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); catalogued as COSV54727447, COSV99547905; called by muse, mutect2, varscan2
- FAM47B | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.122); catalogued as COSV100263890, COSV61455991; called by muse, mutect2, varscan2
- FAM9A | c.127A>G p.T43A | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.139); catalogued as COSV66813607; called by muse, mutect2, varscan2
- FCN1 | c.918G>C p.W306C | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65662745; called by muse, mutect2, varscan2
- FRMPD2 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs1248557124, COSV59716248; called by muse, mutect2, varscan2
- FUT9 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.71); PolyPhen benign (0.103); catalogued as COSV56153184; called by muse, mutect2, varscan2
- GABBR1 | c.1709G>A p.G570E | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV63543948; called by muse, mutect2, varscan2
- GAPVD1 | c.869C>T p.T290I | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.995); catalogued as rs758271475, COSV52926131; called by muse, mutect2, varscan2
- GARRE1 | c.2143C>T p.P715S | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.015); catalogued as COSV100209634; called by mutect2, varscan2
- GARRE1 | c.2144C>A p.P715Q | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV100209637, COSV55101086; called by muse, mutect2, varscan2
- GAS2 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780339322, COSV53410780; called by muse, varscan2
- GIMAP1 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs773050722, COSV56189328; called by muse, mutect2, varscan2
- GLI2 | c.1823C>T p.P608L (on ENST00000361492 / NM_001374353.1; = p.P625L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV100083995; called by muse, mutect2, varscan2
- GPR158 | c.3400C>T p.L1134F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.564); catalogued as COSV66278292, COSV66282936; called by muse, mutect2, varscan2
- GPRC5A | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs150619249; called by muse, mutect2, varscan2
- GPRIN1 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV56140158, COSV56143071; called by muse, mutect2, varscan2
- GRIA1 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99601434; called by mutect2, varscan2
- GRID1 | c.2753G>A p.R918Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.968); catalogued as rs778828614, COSV60044835; called by mutect2, varscan2
- GRIN2B | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV74207138; called by muse, mutect2, varscan2
- GRM6 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs777866804, COSV51447746; called by mutect2, varscan2
- HPGD | c.157T>G p.F53V | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV56663922; called by muse, varscan2
- IGHG2 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1270160693; called by muse, mutect2, varscan2
- INSL6 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as rs1381072524, COSV67563289; called by muse, mutect2, varscan2
- ITGA2 | c.2537C>T p.S846L | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56864719; called by muse, mutect2, varscan2
- ITGA9 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs374117373; called by muse, mutect2, varscan2
- JUP | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as rs782501542, COSV60279208; called by muse, mutect2
- KCNB1 | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.021); catalogued as COSV65567367, COSV65570142; called by muse, mutect2, varscan2
- KCNB2 | c.2642A>T p.E881V | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV73051886; called by mutect2, varscan2
- KCNE3 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59552350; called by muse, mutect2, varscan2
- KIAA1328 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs1349608307, COSV54461542; called by muse, mutect2
- KLC2 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV57583756; called by muse, mutect2, varscan2
- KLHL24 | c.635T>C p.L212P | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54427972; called by muse, mutect2, varscan2
- LAMA1 | c.6189C>T p.A2063= | Splice Region (SNP) | VAF 36/108 reads (33%) | catalogued as COSV67541728; called by muse, mutect2, varscan2
- LAMA1 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745969754, COSV67541730; called by muse, varscan2
- LCE3A | c.91A>T p.S31C | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV59550985; called by muse, mutect2, varscan2
- LIG1 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99619201; called by muse, varscan2
- LILRB4 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.81); catalogued as rs776706290, COSV54405403; called by muse, mutect2, varscan2
- LRBA | c.8366G>A p.R2789Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs749223887, COSV63961121; called by mutect2, varscan2
- LUZP1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56504042; called by muse, mutect2, varscan2
- MAP3K4 | c.4096G>A p.G1366R | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815616, COSV62329900; called by muse, mutect2, varscan2
- MGAM | c.2980C>T p.P994S | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV72074235; called by muse, mutect2, varscan2
- MTA3 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.915); catalogued as COSV68135950; called by muse, mutect2, varscan2
- MTCL1 | c.1255C>T p.R419* (on ENST00000306329 / NM_001378206.1; = p.R59* on NM_015210.4) | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV60407418; called by muse, mutect2, varscan2
- MUC16 | c.23873C>T p.S7958L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as COSV67482481; called by muse, mutect2, varscan2
- NAV2 | c.5496C>T p.V1832= (on ENST00000396087 / NM_001244963.2; = p.V1776= on NM_182964.6) | Splice Region (SNP) | VAF 42/98 reads (43%) | catalogued as rs1308525401, COSV100215863; called by mutect2, varscan2
- NDST3 | c.1603G>C p.V535L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV56626008; called by muse, mutect2, varscan2
- NEUROD4 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.435); catalogued as COSV54471673, COSV54473361; called by muse, mutect2, varscan2
- NOS1 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.219); catalogued as COSV57606672; called by muse, mutect2, varscan2
- NUP210 | c.4876G>A p.D1626N | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV54407724, COSV54414375; called by muse, varscan2
- OR10X1 | c.297A>T p.E99D | Missense Mutation (SNP) | VAF 56/78 reads (72%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV63767775; called by muse, mutect2, varscan2
- OR13D1 | c.653A>T p.K218I | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV59514497; called by mutect2, varscan2
- OR2T2 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61618575; called by mutect2, varscan2
- OR2T35 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100442363; called by mutect2, varscan2
- OR4M1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 86/336 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs760327097, COSV60059765, COSV60060322, COSV60060528; called by muse, mutect2, varscan2
- OR51B2 | c.894A>C p.Q298H | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV60917351; called by muse, mutect2, varscan2
- OR52E2 | c.775T>A p.S259T | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.85); catalogued as COSV58613228; called by muse, mutect2, varscan2
- OR52R1 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); catalogued as COSV100617733, COSV61887852; called by muse, mutect2, varscan2
- OR5D16 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as COSV65722599; called by muse, mutect2, varscan2
- OSBP | c.1562G>A p.S521N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV99803258; called by muse, mutect2, varscan2
- PAN2 | c.3588C>A p.F1196L (on ENST00000425394 / NM_001127460.3; = p.F1192L on NM_014871.5) | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV56264893; called by mutect2, varscan2
- PCDH18 | c.2272G>T p.D758Y | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61269227, COSV61270908; called by muse, mutect2, varscan2
- PCDHB1 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV60632569; called by muse, mutect2, varscan2
- PCDHB3 | c.1563C>G p.Y521* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV50607432, COSV50625007; called by muse, mutect2, varscan2
- PCMTD2 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs746565490, COSV55061737; called by muse, mutect2, varscan2
- PDHA1 | c.692C>T p.T231M | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1272572107, CM001279, COSV58835380; called by muse, mutect2, varscan2
- PDZRN4 | c.2805G>A p.M935I (on ENST00000402685 / NM_001164595.2; = p.M677I on NM_013377.4) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV54211414; called by muse, mutect2, varscan2
- PIGH | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | catalogued as COSV53615079; called by muse, mutect2
- PLEKHG6 | c.1462C>T p.L488F | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs749207197, COSV50607285; called by muse, mutect2, varscan2
- POLG | c.271G>A p.G91R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV51523944; called by muse, mutect2, varscan2
- POLR3B | c.2911G>A p.D971N | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV57282813; called by muse, mutect2, varscan2
- POSTN | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.05); catalogued as COSV65714036; called by muse, mutect2, varscan2
- PPP1R3A | c.2333G>A p.G778E | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52889549; called by muse, mutect2, varscan2
- PRAM1 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV55315878; called by muse, mutect2, varscan2
- PRDM12 | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53389792, COSV53392061; called by muse, mutect2, varscan2
- PRG4 | c.3559G>A p.E1187K | Missense Mutation (SNP) | VAF 76/125 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV63356171; called by muse, mutect2, varscan2
- PRRC2B | c.487C>G p.R163G | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61941410; called by muse, mutect2, varscan2
- PYGL | c.2462A>T p.Y821F | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53587812; called by muse, mutect2, varscan2
- QTRT1 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV51550764, COSV51552352; called by muse, mutect2, varscan2
- RASGRP3 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.137); catalogued as COSV67824164; called by muse, mutect2, varscan2
- RASSF9 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs569219332, COSV63435284; called by muse, mutect2, varscan2
- RB1 | c.1382T>C p.L461P | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57314075; called by muse, mutect2, varscan2
- RBPMS | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as rs745752899, COSV55125958; called by muse, varscan2
- RGS12 | c.3316C>T p.P1106S | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as rs777283306, COSV58754193; called by muse, mutect2, varscan2
- RGS12 | c.3317C>T p.P1106L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs751311594, COSV100123190; called by muse, mutect2, varscan2
- RICTOR | c.1438C>T p.H480Y | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV57127826; called by muse, mutect2, varscan2
- RIMS1 | c.4747G>A p.E1583K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV53474179; called by muse, mutect2, varscan2
- RNASEH2A | c.584T>C p.F195S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs773609935, COSV55552497; called by muse, varscan2
- RYR1 | c.11216G>A p.G3739E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62104847, COSV62105892; called by muse, mutect2
- SALL1 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.197); catalogued as COSV51762198; called by muse, mutect2, varscan2
- SERPINI1 | c.482-1G>A p.X161_splice | Splice Site (SNP) | VAF 22/52 reads (42%) | catalogued as COSV55513499; called by muse, mutect2, varscan2
- SETX | c.4387G>A p.D1463N | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV56391569; called by muse, mutect2, varscan2
- SH3TC2 | c.3293C>A p.T1098N | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV60466379, COSV99072918; called by muse, mutect2, varscan2
- SLC24A3 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60127724; called by muse, mutect2, varscan2
- SLC25A27 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 122/205 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.098); catalogued as COSV51498188; called by muse, mutect2, varscan2
- SLC2A14 | c.183C>T p.I61= | Splice Region (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100533619, COSV61587993; called by muse, mutect2, varscan2
- SLC4A10 | c.1120C>T p.L374F (on ENST00000446997 / NM_001354461.2; = p.L344F on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55792667; called by muse, mutect2, varscan2
- SLC6A14 | c.50A>G p.K17R | Missense Mutation (SNP) | VAF 115/383 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV64148078; called by muse, mutect2, varscan2
- SLITRK2 | c.1823C>T p.S608F | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV59427757; called by muse, mutect2, varscan2
- SLITRK4 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 43/136 reads (32%) | catalogued as COSV100567388, COSV62025472; called by muse, mutect2, varscan2
- SMARCD3 | c.389G>A p.R130K (on ENST00000262188 / NM_001003801.2; = p.R117K on NM_003078.4) | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.171); catalogued as COSV99223274; called by muse, mutect2, varscan2
- SMTNL1 | c.1115G>A p.S372N (on ENST00000399154; = p.S409N on NM_001105565.2) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV67700519; called by muse, mutect2, varscan2
- SOX7 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.702); catalogued as COSV58731421; called by muse, varscan2
- SPAG6 | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV57622730; called by muse, mutect2, varscan2
- SPRED3 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58313578; called by muse, mutect2, varscan2
- SPTBN5 | c.5068C>G p.Q1690E | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.388); catalogued as COSV58025657; called by muse, varscan2
- ST18 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52504218; called by muse, mutect2, varscan2
- STXBP5L | c.2435C>T p.S812F | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs866064328, COSV56505589; called by muse, mutect2, varscan2
- SUGP2 | c.1508G>C p.G503A | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1279641258, COSV58262987; called by muse, mutect2, varscan2
- TCF4 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV61903246; called by muse, mutect2, varscan2
- TENM3 | c.6964G>A p.G2322R | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69315388; called by muse, mutect2, varscan2
- TET1 | c.5092G>A p.V1698I | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.271); catalogued as COSV65387888; called by muse, mutect2, varscan2
- TEX26 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV66839819, COSV66840331; called by muse, mutect2, varscan2
- TG | c.3071C>T p.S1024L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs962077113, COSV55088966; called by muse, mutect2, varscan2
- TGFBR2 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 89/219 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs143095746, COSV55445636; ClinVar: likely benign; called by mutect2, varscan2
- TGIF2 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs765074141, COSV100872324; called by mutect2, varscan2
- THSD7B | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 86/201 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55721201; called by muse, mutect2, varscan2
- TLR8 | c.2674T>A p.S892T (on ENST00000218032 / NM_138636.5; = p.S910T on NM_016610.4) | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.726); catalogued as COSV54319615; called by mutect2, varscan2
- TMEM108 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.073); catalogued as rs140878635, COSV100418957, COSV58865927; called by muse, mutect2, varscan2
- TMEM182 | c.662T>C p.V221A | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV68425321; called by muse, mutect2
- TMEM63C | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs771625646; called by mutect2, varscan2
- TPH2 | c.227G>A p.G76E | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV61593484; called by muse, mutect2, varscan2
- TRPM4 | c.2126C>T p.T709I | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs375349363, COSV53266946; called by muse, mutect2, varscan2
- TTC30B | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as rs777779414, COSV68809266, COSV68809725; called by muse, mutect2, varscan2
- TTN | c.28447G>A p.D9483N (on ENST00000591111; = p.D8556N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | PolyPhen benign (0.118); catalogued as COSV60244303; called by mutect2, varscan2
- TTN | c.14872G>A p.G4958R (on ENST00000591111; = p.G4031R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/201 reads (25%) | PolyPhen probably damaging (1); catalogued as rs1019067272, COSV100623603, COSV60244311; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UAP1 | c.1451C>T p.S484F (on ENST00000271469 / NM_001324116.1; = p.S467F on NM_003115.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 139/215 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54852767; called by muse, mutect2, varscan2
- UBE4B | c.1604C>T p.S535F (on ENST00000343090 / NM_001105562.3; = p.S406F on NM_006048.5) | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); catalogued as COSV53538746; called by muse, mutect2, varscan2
- UMODL1 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as COSV68557152; called by muse, mutect2, varscan2
- USP9X | c.4086+2T>G p.X1362_splice | Splice Site (SNP) | VAF 46/118 reads (39%) | catalogued as COSV61073316; called by muse, mutect2, varscan2
- USP9X | c.4471G>A p.V1491I | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.395); catalogued as COSV61073326; called by muse, mutect2, varscan2
- WIPF1 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1181632515, COSV55816968, COSV99768236; called by muse, mutect2, varscan2
- XAGE3 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV60569803; called by muse, mutect2, varscan2
- ZBED1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.077); catalogued as rs373098167, COSV58134376; called by muse, mutect2, varscan2
- ZMYND15 | c.227A>G p.E76G | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.275); catalogued as COSV52643790; called by muse, mutect2, varscan2
- ZNF142 | c.3436C>T p.P1146S (on ENST00000411696 / NM_001379660.1; = p.P946S on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV68744955; called by muse, mutect2, varscan2
- ZNF283 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs764624758, COSV60289026; called by muse, mutect2, varscan2
- ZNF556 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV56913496; called by muse, mutect2, varscan2
- ZNF574 | c.1183C>T p.P395S | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as rs756335478, COSV55905907; called by muse, varscan2
- ZNF813 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 37/104 reads (36%) | catalogued as COSV101124673, COSV101124695; called by muse, mutect2, varscan2
- ZNF875 | c.1397T>C p.V466A | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV60992931, COSV60994667; called by muse, mutect2, varscan2
- LRRC17 | c.643_644del p.E215Rfs*21 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | called by mutect2, varscan2*
- OR13C8 | c.301del p.M101Cfs*13 | Frame Shift Del (DEL) | VAF 37/144 reads (26%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 176/367 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- RBP3 | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); called by mutect2, varscan2
- SUPT20HL2 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TRAV10 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ABCA12 | c.591C>T p.F197= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as COSV55952052, COSV55970111, COSV55974804; called by muse, mutect2, varscan2
- ADGRF4 | c.123G>A p.G41= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs1362423369, COSV51953295; called by mutect2, varscan2
- AGFG2 | c.1119C>T p.A373= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV53546547; called by muse, mutect2, varscan2
- ALOX5AP | c.345G>A p.G115= | Silent (SNP) | VAF 127/255 reads (50%) | catalogued as COSV66858235; called by muse, mutect2, varscan2
- AMOTL2 | c.2245C>T p.L749= (on ENST00000422605; = p.L750= on NM_016201.4) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV51440330; called by muse, mutect2, varscan2
- ATG2A | c.5736C>T p.L1912= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as rs188923974; called by muse, mutect2, varscan2
- ATRX | c.2991C>T p.D997= | Silent (SNP) | VAF 44/170 reads (26%) | catalogued as COSV64881011; called by muse, mutect2, varscan2
- ATXN7 | c.1062C>T p.T354= | Silent (SNP) | VAF 48/137 reads (35%) | catalogued as COSV55754598; called by muse, varscan2
- C10orf71 | c.1050G>A p.G350= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs373739260, COSV60504006, COSV60515785; called by mutect2, varscan2
- C2 | c.978C>T p.A326= | Silent (SNP) | VAF 69/328 reads (21%) | catalogued as rs756413100, COSV54961952; called by muse, mutect2, varscan2
- CACNG3 | c.240C>T p.I80= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as rs765043632, COSV50066291; called by mutect2, varscan2
- CAMTA1 | c.4158C>T p.C1386= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as rs780992004, COSV57883289; called by muse, varscan2
- CBX6 | c.369C>T p.I123= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99328243; called by mutect2, varscan2
- CCDC7 | c.3921C>T p.P1307= | Silent (SNP) | VAF 54/134 reads (40%) | catalogued as COSV56549167; called by muse, mutect2, varscan2
- CDKL2 | c.789A>G p.L263= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV56734793; called by muse, mutect2, varscan2
- CEACAM21 | c.222G>A p.E74= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV51815716; called by muse, mutect2, varscan2
- CNTN5 | c.2805C>T p.V935= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as COSV54341387; called by mutect2, varscan2
- CPB1 | c.867C>T p.F289= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as COSV51575789; called by muse, varscan2
- CYP27C1 | c.507G>A p.E169= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV58867686; called by muse, mutect2, varscan2
- DARS2 | c.372C>T p.S124= | Silent (SNP) | VAF 12/147 reads (8%) | catalogued as COSV99508852; called by muse, mutect2
- DDB1 | c.1353C>T p.F451= | Silent (SNP) | VAF 76/185 reads (41%) | catalogued as rs768415837, COSV57104857; called by muse, mutect2, varscan2
- DENND3 | c.2874G>A p.Q958= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV52805216; called by muse, mutect2, varscan2
- DGCR2 | c.1350C>T p.P450= | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- DNAJB8 | c.72C>T p.R24= | Silent (SNP) | VAF 38/111 reads (34%) | catalogued as COSV59879287; called by muse, mutect2, varscan2
- DOCK3 | c.5937C>T p.H1979= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs565926939, COSV56540212; called by muse, varscan2
- DSC1 | c.1140G>A p.Q380= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV57149522; called by muse, mutect2, varscan2
- ELN | c.271C>T p.L91= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV52713652; called by muse, mutect2, varscan2
- EPHX2 | c.657C>T p.I219= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs747183411, COSV66845653; called by muse, mutect2, varscan2
- ERAP2 | c.2784G>A p.L928= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as COSV65940902; called by muse, mutect2, varscan2
- ERC2 | c.1651T>C p.L551= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs747423199, COSV55649410; called by muse, mutect2
- FAAH2 | c.1473G>A p.L491= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV66510502; called by mutect2, varscan2
- FBXL14 | c.1206G>A p.G402= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs905687769, COSV59337322; called by muse, mutect2, varscan2
- FLNB | c.3930C>T p.D1310= | Silent (SNP) | VAF 40/114 reads (35%) | catalogued as rs150901141; ClinVar: benign; called by mutect2, varscan2
- GABRE | c.993C>T p.F331= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV64818769; called by muse, mutect2, varscan2
- GANC | c.1860C>T p.F620= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as COSV58810893; called by mutect2, varscan2
- GLCCI1 | c.1362C>T p.I454= | Silent (SNP) | VAF 92/297 reads (31%) | catalogued as rs960199685, COSV56204048; called by muse, mutect2, varscan2
- HAP1 | c.1812G>A p.R604= (on ENST00000310778 / NM_001367460.1; = p.R552= on NM_177977.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 74/167 reads (44%) | catalogued as COSV57880032; called by muse, mutect2, varscan2
- HHAT | c.600C>T p.S200= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as rs897408562, COSV54805770; called by muse, mutect2, varscan2
- IFNA7 | c.432G>A p.R144= | Silent (SNP) | VAF 80/243 reads (33%) | catalogued as COSV53331209; called by muse, mutect2, varscan2
- IL1RL1 | c.603G>A p.T201= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs201621624, COSV52119058, COSV99293858; called by muse, mutect2, varscan2
- IQCF1 | c.15G>A p.Q5= | Silent (SNP) | VAF 123/333 reads (37%) | catalogued as COSV58823149, COSV58823845; called by muse, mutect2, varscan2
- ITGAX | c.2025G>A p.V675= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as COSV51649601; called by mutect2, varscan2
- KAT6B | c.4059G>A p.E1353= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV54752327; called by muse, mutect2, varscan2
- KCNH5 | c.963T>C p.S321= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV59770957; called by muse, mutect2, varscan2
- KNTC1 | c.5874C>T p.S1958= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV61082794; called by muse, mutect2, varscan2
- LIG1 | c.1797G>A p.P599= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs368088071; called by muse, varscan2
- LRIT2 | c.1560C>T p.S520= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV60564803; called by muse, mutect2, varscan2
- LRRC10 | c.831C>T p.S277= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV64060599; called by muse, mutect2, varscan2
- LY9 | c.447C>T p.F149= | Silent (SNP) | VAF 70/111 reads (63%) | catalogued as rs373033533, COSV54434619; called by muse, mutect2, varscan2
- MPPED2 | c.414C>T p.F138= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV63900339; called by muse, mutect2, varscan2
- MUC16 | c.5220T>C p.A1740= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as COSV67482488; called by muse, mutect2, varscan2
- MYH8 | c.5106G>A p.R1702= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs140525529, COSV67965310; called by muse, mutect2, varscan2
- NAALAD2 | c.831G>A p.V277= | Silent (SNP) | VAF 64/199 reads (32%) | catalogued as COSV58964428; called by muse, mutect2, varscan2
- NEO1 | c.4221G>A p.R1407= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV56076326; called by muse, mutect2, varscan2
- NFIC | c.745C>T p.L249= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV59415231; called by muse, mutect2, varscan2
- NLRP10 | c.810G>A p.K270= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV100149967, COSV60781704; called by muse, mutect2, varscan2
- OR52M1 | c.855C>T p.L285= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs1460409748, COSV64172506; called by muse, mutect2, varscan2
- OTOGL | c.5085G>A p.R1695= (on ENST00000547103; = p.R1686= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 2/10 reads (20%) | catalogued as rs1305357865, COSV54016458, COSV54021130; called by mutect2, varscan2
- PCDHB7 | c.1845C>T p.F615= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as rs543710725, COSV50760517; called by muse, mutect2, varscan2
- PI4K2A | c.627C>T p.P209= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV65702031; called by muse, mutect2, varscan2
- PIK3R4 | c.3948C>T p.T1316= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV62033254; called by muse, mutect2, varscan2
- PLCG1 | c.1722C>T p.I574= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs146548575, COSV54821912; called by muse, mutect2, varscan2
- PLEKHG2 | c.1434C>T p.G478= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV52687976; called by muse, varscan2
- PLEKHM3 | c.1017C>T p.F339= | Silent (SNP) | VAF 20/96 reads (21%) | catalogued as COSV66818121; called by muse, varscan2
- PNMA3 | c.1323G>A p.Q441= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV64722774; called by muse, mutect2, varscan2
- POP1 | c.1017C>T p.I339= | Silent (SNP) | VAF 72/143 reads (50%) | catalogued as COSV62893828; called by muse, mutect2, varscan2
- PSAPL1 | c.1143C>T p.I381= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs139203507, COSV59844046; called by mutect2, varscan2
- PSD2 | c.1770C>T p.S590= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as COSV51206339; called by muse, mutect2, varscan2
- PTPN14 | c.2667C>T p.T889= | Silent (SNP) | VAF 14/100 reads (14%) | catalogued as COSV65286698; called by muse, mutect2, varscan2
- R3HDM1 | c.1647C>T p.S549= | Silent (SNP) | VAF 69/179 reads (39%) | catalogued as COSV51530082; called by muse, mutect2, varscan2
- RALGDS | c.1920C>T p.N640= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs753298695, COSV64428990; called by muse, mutect2, varscan2
- REPIN1 | c.1578G>A p.Q526= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs1399219687, COSV101262669; called by muse, mutect2, varscan2
- RERGL | c.606G>A p.R202= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV57461035; called by muse, varscan2
- RGS8 | c.408G>A p.Q136= (on ENST00000367556 / NM_001369564.2; = p.Q154= on NM_033345.3) | Silent (SNP) | VAF 104/160 reads (65%) | catalogued as COSV51118664; called by muse, mutect2, varscan2
- SCN2A | c.2311T>C p.L771= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV51851093; called by muse, mutect2, varscan2
- SH3BGRL | c.201T>G p.P67= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV100943471; called by muse, mutect2, varscan2
- SLC35F3 | c.639C>T p.L213= (on ENST00000366617 / NM_001300845.1; = p.L282= on NM_173508.4) | Silent (SNP) | VAF 269/394 reads (68%) | catalogued as rs1159088857, COSV64019810; called by muse, mutect2, varscan2
- SMARCD3 | c.390G>A p.R130= (on ENST00000262188 / NM_001003801.2; = p.R117= on NM_003078.4) | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV99223271; called by muse, mutect2, varscan2
- TENM1 | c.6648C>T p.G2216= | Silent (SNP) | VAF 42/101 reads (42%) | catalogued as COSV64439294; called by muse, mutect2, varscan2
- TGIF2 | c.318C>T p.P106= | Silent (SNP) | VAF 37/126 reads (29%) | catalogued as COSV100872322; called by muse, mutect2, varscan2
- TIAM2 | c.3828G>A p.L1276= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as COSV51643365, COSV99265516; called by mutect2, varscan2
- TRMT2B | c.429T>A p.I143= | Silent (SNP) | VAF 136/298 reads (46%) | catalogued as COSV58620522; called by muse, mutect2, varscan2
- UGT1A1 | c.1029G>A p.S343= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as rs1468683280, COSV59392648; called by muse, mutect2, varscan2
- UNC13B | c.3744G>A p.G1248= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV65937366; called by muse, mutect2, varscan2
- VPS13D | c.6306C>T p.S2102= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV50640942; called by muse, mutect2, varscan2
- VSTM4 | c.264G>A p.G88= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs267602504, COSV53677010; called by muse, mutect2, varscan2
- WIPF1 | c.108C>T p.L36= | Silent (SNP) | VAF 35/135 reads (26%) | catalogued as rs753986212, COSV99769170; called by muse, mutect2, varscan2
- WNK3 | c.4548A>G p.P1516= | Silent (SNP) | VAF 75/224 reads (33%) | catalogued as COSV63615336; called by muse, mutect2, varscan2
- XAB2 | c.399C>T p.F133= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs749533723, COSV60696867; called by muse, mutect2, varscan2
- XPO6 | c.3168C>T p.V1056= | Silent (SNP) | VAF 15/34 reads (44%) | catalogued as rs1306504448, COSV58963094; called by muse, mutect2, varscan2
- ZNF284 | c.156C>T p.S52= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV69691500; called by muse, mutect2, varscan2
- ZZEF1 | c.655C>T p.L219= | Silent (SNP) | VAF 50/178 reads (28%) | catalogued as COSV67559423; called by muse, mutect2, varscan2
- BTBD7 | c.1162+5191T>C | Intron (SNP) | VAF 47/148 reads (32%) | catalogued as COSV100108146; called by muse, mutect2, varscan2
- CCNQP1 | n.531C>T | RNA (SNP) | VAF 24/39 reads (62%) | catalogued as rs371670349; called by mutect2, varscan2
- DNAH8 | chr6:38722870 G>A | 5'Flank (SNP) | VAF 25/33 reads (76%) | catalogued as rs1240681880, COSV59433666; called by muse, mutect2, varscan2
- MIR410 | n.21C>T | RNA (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- OR51I2 | c.*1C>A | 3'UTR (SNP) | VAF 28/91 reads (31%) | catalogued as COSV100413442; called by muse, mutect2, varscan2
- REG4 | c.*445C>T | 3'UTR (SNP) | VAF 52/117 reads (44%) | catalogued as COSV99858490; called by muse, mutect2, varscan2
- SNORD116-15 | n.46A>G | RNA (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- SNORD116-17 | n.31C>T | RNA (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2, varscan2
- TTN | c.10303+1222G>A | Intron (SNP) | VAF 24/111 reads (22%) | catalogued as rs759465333, COSV60368938, COSV60382715; ClinVar: likely benign; called by muse, mutect2, varscan2
- XIST | n.8755C>T | RNA (SNP) | VAF 14/42 reads (33%) | catalogued as rs1162704710; called by muse, mutect2, varscan2
- ZFP36L1 | chr14:68796166 C>T | 5'Flank (SNP) | VAF 17/46 reads (37%) | called by muse, mutect2, varscan2
